Gene-level copy-number profile of tumor specimen TCGA-G3-AAV1-01A from TCGA case TCGA-G3-AAV1, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.9 years (18,973 days).
Specimen TCGA-G3-AAV1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.3940ef72-201d-4ce1-a352-b92be76bcca6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G3-AAV1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2e2ba488-43c8-47ff-8b2b-b26adc109717

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 222; copy number 2: 7,716; copy number 3: 18,851; copy number 4: 26,863; copy number 5: 2,236; copy number 6: 3,920; copy number 8: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G3-AAV1-01A-11D-A381-01): tumor purity 0.74, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:135,851,701–136,195,574, 1 gene (within-gene range 0–2): PDE7B.
- chr6:135,882,780–136,225,751, 3 genes (within-gene range 0–2): AL360178.2, AL138828.1, COX5BP2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 222. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
